Somatic mutation profile of tumor specimen TARGET-30-PATNEA-01A (aliquot TARGET-30-PATNEA-01A-01D) from TARGET case TARGET-30-PATNEA, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.4 years (1,234 days).
Specimen TARGET-30-PATNEA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc2e6b64-65d9-43ff-8d06-5883d9f6b8d4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATNEA-10A (Blood Derived Normal), aliquot TARGET-30-PATNEA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84ccdcdb-d0f3-4e71-bea8-92b15efb7810

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH2 | c.12436G>T p.G4146* | Nonsense Mutation (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- ATP1A2 | c.1026G>A p.L342= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV63406537; called by muse, mutect2, varscan2
- KMT2C | c.7560A>T p.V2520= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
